Somatic mutation profile of tumor specimen TCGA-CV-7434-01A (aliquot TCGA-CV-7434-01A-11D-2129-08) from TCGA case TCGA-CV-7434, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.2 years (23,465 days).
Specimen TCGA-CV-7434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4f985f2-19f8-4070-994c-6aed1cce1932.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7434-10A (Blood Derived Normal), aliquot TCGA-CV-7434-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0202d4e9-71dd-47fd-8fca-3e2cfbf26386

The open-access MAF lists 98 somatic variants for this specimen: 73 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 23, Nonsense Mutation 8, Splice Site 3, Frame Shift Del 3, 5'Flank 1, Intron 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.5998C>T p.Q2000* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as rs1565798715, COSV56469607; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACADVL | c.584A>G p.K195R | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as COSV50035591, COSV99138998; called by muse, mutect2, varscan2
- ACSM2B | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV61658381; called by muse, mutect2, varscan2
- ACSS3 | c.968C>A p.S323* | Nonsense Mutation (SNP) | VAF 22/77 reads (29%) | catalogued as COSV99699638; called by muse, mutect2, varscan2
- ADGRA3 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775111076, COSV99293898; called by muse, mutect2, varscan2
- AFG1L | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 133/212 reads (63%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs186208029; called by muse, mutect2, varscan2
- ANKRD35 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV62911357; called by muse, mutect2
- ANKRD36 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101347573; called by muse, mutect2, varscan2
- ARMC9 | c.1949T>A p.L650Q | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100590173; called by muse, mutect2, varscan2
- ATP11B | c.2383A>G p.M795V | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs1197831062, COSV60026101; called by muse, mutect2, varscan2
- C1orf198 | c.138C>A p.D46E | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.92); PolyPhen benign (0.059); catalogued as COSV100793522; called by muse, mutect2, varscan2
- CCDC159 | c.710A>T p.Q237L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99264832; called by muse, varscan2
- CCDC50 | c.1138-2A>C p.X380_splice (on ENST00000392455 / NM_178335.3; = p.X204_splice on NM_174908.4) | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as COSV101165352, COSV66668750; called by muse, mutect2, varscan2
- CENPBD1 | c.40A>C p.S14R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99240847; called by muse, mutect2, varscan2
- CENPE | c.3671G>C p.R1224T | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV54386990; called by muse, mutect2, varscan2
- CMKLR1 | c.461G>A p.R154H (on ENST00000312143 / NM_001142344.2; = p.R152H on NM_004072.3) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs749502814, COSV100379298, COSV56436930; called by muse, mutect2, varscan2
- CNKSR2 | c.870C>G p.I290M | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV99670238; called by muse, mutect2, varscan2
- CREBBP | c.4309A>T p.I1437F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV52112675; called by muse, mutect2
- CREBBP | c.4308T>G p.S1436R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52128106, COSV99272893; called by muse, mutect2, varscan2
- CSF2RB | c.249G>A p.W83* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99454656; called by muse, varscan2
- CSNK2A1 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 42/123 reads (34%) | catalogued as rs1380843831, COSV53934311; called by muse, mutect2, varscan2
- CTNNA3 | c.1536C>A p.S512R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV101052128, COSV65612208; called by muse, mutect2
- DDIT4 | c.226del p.V76Cfs*21 | Frame Shift Del (DEL) | VAF 54/190 reads (28%) | catalogued as COSV56578138; called by mutect2, pindel, varscan2
- DESI1 | c.239C>G p.T80R | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV99611062; called by muse, mutect2, varscan2
- ERCC4 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as rs139197943; called by muse, mutect2, varscan2
- FAM135B | c.1591G>C p.V531L | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52737749, COSV99428655; called by muse, mutect2, varscan2
- FARSB | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99918242; called by muse, mutect2, varscan2
- FASLG | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as COSV100390744; called by muse, mutect2, varscan2
- FMNL3 | c.1967G>T p.R656L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV99527237; called by muse, mutect2, varscan2
- GRIA4 | c.2179G>T p.E727* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV99235406; called by muse, mutect2, varscan2
- GRIK2 | c.2546dup p.N849Kfs*11 | Frame Shift Ins (INS) | VAF 62/174 reads (36%) | catalogued as rs760757380; called by mutect2, varscan2
- HIPK1 | c.2201G>T p.G734V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV100479804; called by muse, mutect2, varscan2
- ISM1 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768938941, COSV52603958; called by mutect2, varscan2
- KCNT2 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as rs528303127, COSV54092992; called by muse, mutect2, varscan2
- MGAT5B | c.2215A>T p.M739L (on ENST00000569840 / NM_001199172.2; = p.M737L on NM_144677.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.811); catalogued as rs1483557306, COSV56930217; called by muse, mutect2, varscan2
- MN1 | c.3030G>C p.W1010C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV100179785; called by muse, mutect2, varscan2
- NBPF1 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV101236871; called by muse, mutect2, varscan2
- NTRK1 | c.1640A>C p.K547T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100693894; called by muse, mutect2, varscan2
- OBSCN | c.3848C>A p.A1283D | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV99486057; called by muse, mutect2, varscan2
- ODR4 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.793); catalogued as COSV99834549; called by muse, mutect2, varscan2
- OR5D14 | c.784T>A p.C262S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV100162679; called by muse, mutect2, varscan2
- OSBP2 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60240986; called by muse, mutect2, varscan2
- OSTM1 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.594); catalogued as rs1235602665, COSV99514372; called by muse, mutect2, varscan2
- PA2G4 | c.1169A>G p.N390S | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV100306701; called by muse, mutect2, varscan2
- PHF20 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100180846; called by muse, mutect2, varscan2
- PLA2G4E | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV101268663; called by muse, mutect2, varscan2
- PTPRT | c.3602G>T p.R1201L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100631324, COSV61969750; called by muse, mutect2, varscan2
- RAB5C | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100651513; called by muse, mutect2, varscan2
- RASAL2 | c.1655C>G p.S552C | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100862999; called by muse, mutect2, varscan2
- RSBN1 | c.1793T>C p.V598A | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99793681; called by muse, mutect2, varscan2
- SEC23A | c.2123C>T p.T708I | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100305945; called by muse, mutect2, varscan2
- SEC24B | c.2420G>T p.R807L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54498557, COSV54502109; called by muse, mutect2, varscan2
- SHISA5 | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV99604245; called by muse, mutect2, varscan2
- SHROOM3 | c.4483C>T p.R1495W | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs368105376; called by muse, mutect2, varscan2
- SOS2 | c.3248C>A p.P1083Q | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99366948; called by muse, mutect2, varscan2
- SPEN | c.1882C>G p.Q628E | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV101005744; called by muse, mutect2, varscan2
- SRSF6 | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99719878; called by muse, mutect2, varscan2
- TEX10 | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100887994; called by muse, mutect2, varscan2
- TMEM168 | c.626C>A p.A209E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100454852; called by muse, mutect2, varscan2
- TNRC18 | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101259538; called by muse, mutect2, varscan2
- TP53 | c.403del p.C135Afs*35 | Frame Shift Del (DEL) | VAF 21/40 reads (53%) | catalogued as COSV52674321, COSV52706302, COSV52827707; called by mutect2, pindel, varscan2
- TPP2 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV101060512; called by muse, mutect2, varscan2
- TTC7B | c.2390C>A p.A797D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV100127251, COSV100128778; called by muse, mutect2, varscan2
- VSX1 | c.943G>T p.V315L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100942239; called by muse, mutect2, varscan2
- ZC3H14 | c.1347G>A p.M449I | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99193328; called by muse, mutect2, varscan2
- ZIC1 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV99292588; called by muse, mutect2, varscan2
- ZNF333 | c.127+1G>A p.X43_splice | Splice Site (SNP) | VAF 14/40 reads (35%) | catalogued as rs745612680, COSV99469677; called by muse, mutect2, varscan2
- ZNF510 | c.962C>G p.S321* | Nonsense Mutation (SNP) | VAF 27/112 reads (24%) | catalogued as COSV56296617; called by muse, mutect2, varscan2
- ZNF546 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as rs777270235, COSV100713595; called by muse, mutect2, varscan2
- ZNF671 | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100235313; called by muse, mutect2, varscan2
- DCBLD1 | c.1495+3del p.X499_splice | Splice Site (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- ME1 | c.1238_1243del p.A413_C415delinsG | In Frame Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel
- ZNF251 | c.1206_1207del p.K403Tfs*5 | Frame Shift Del (DEL) | VAF 36/252 reads (14%) | called by pindel, varscan2
- ADAMTS8 | c.2235C>T p.N745= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs368658938; called by muse, mutect2, varscan2
- AP2A1 | c.1245G>A p.T415= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs543455936, COSV62819569; called by muse, mutect2, varscan2
- ATRX | c.7131A>G p.Q2377= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as COSV100971655; called by muse, mutect2, varscan2
- CACNA1B | c.831C>T p.C277= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as rs778540767, COSV99500558; called by muse, mutect2, varscan2
- CCDC159 | c.708G>T p.L236= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99264828; called by muse, varscan2
- CCDC85A | c.717G>A p.K239= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs774821369, COSV101339599; called by muse, mutect2, varscan2
- CDH2 | c.285C>G p.L95= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV52277616, COSV99299004; called by muse, mutect2, varscan2
- CLN3 | c.417C>T p.G139= (on ENST00000360019 / NM_001286104.2; = p.G163= on NM_000086.2) | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs1351033566, COSV100343783; called by muse, mutect2
- COL11A1 | c.1818G>A p.P606= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as rs748195901, COSV62187907; called by muse, mutect2, varscan2
- CPT1A | c.1125C>T p.P375= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as rs777650233, COSV99681701; called by muse, varscan2
- CTBP2 | c.804G>T p.V268= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV100457110; called by muse, mutect2, varscan2
- CYTH4 | c.387C>T p.F129= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs527608462, COSV99958262; called by muse, mutect2, varscan2
- EPHB1 | c.1677C>T p.I559= | Silent (SNP) | VAF 35/154 reads (23%) | catalogued as rs752991432, COSV101214793; called by muse, mutect2, varscan2
- FLG | c.1524G>A p.A508= | Silent (SNP) | VAF 156/463 reads (34%) | catalogued as rs148161383; called by muse, mutect2, varscan2
- INSL4 | c.396A>G p.G132= | Silent (SNP) | VAF 39/144 reads (27%) | catalogued as COSV99497157, COSV99497267; called by muse, mutect2, varscan2
- JAK3 | c.3027C>T p.D1009= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV101513046; called by muse, mutect2, varscan2
- KCNA2 | c.342G>A p.R114= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100316177; called by muse, mutect2, varscan2
- MARK2 | c.411A>G p.V137= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV100159252; called by muse, mutect2, varscan2
- NR4A1 | c.1374C>A p.G458= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV54482611, COSV99671366, COSV99671878; called by muse, mutect2, varscan2
- PCDH9 | c.87T>A p.T29= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100124460; called by muse, mutect2, varscan2
- PLXNB1 | c.5439G>T p.G1813= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV99603618; called by muse, mutect2, varscan2
- SIGLEC10 | c.1848A>G p.T616= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV100219522; called by muse, mutect2, varscan2
- TIMD4 | c.1068A>T p.G356= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99192461; called by muse, mutect2, varscan2
- CTBP1 | chr4:1250869 C>T | 5'Flank (SNP) | VAF 20/55 reads (36%) | catalogued as rs576852814; called by muse, mutect2, varscan2
- HELT | c.133-114C>T | Intron (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100133029; called by muse, mutect2
